Gene-level copy-number profile of tumor specimen TCGA-UF-A71A-06A from TCGA case TCGA-UF-A71A, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 67.4 years (24,623 days).
Specimen TCGA-UF-A71A-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.f8c7d038-1182-42d0-8787-b84b5ca57eaf.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UF-A71A-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 403 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/afb47d74-f7c3-4a5a-b3b7-494eb9ee20f7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 348; copy number 1: 805; copy number 2: 16,874; copy number 3: 25,734; copy number 4: 5,549; copy number 5: 4,776; copy number 6: 3,895; copy number 7: 343; copy number 8: 971; copy number 9: 642; copy number 10: 217; copy number 11: 58; copy number 15: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UF-A71A-06A-11D-A390-01): tumor purity 0.8, ploidy 3.19, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–181,006,727, 4 genes (within-gene range 0–5): AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr8:18,979,619–19,000,952, 2 genes (within-gene range 0–2): SNORA62, AC009884.1.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–2): MTAP, AL359922.1.
- chr9:21,858,910–21,995,301, 5 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr10:60,684,505–60,741,828, 2 genes (within-gene range 0–2): ARL4AP1, ANK3-DT.
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.
- chr13:110,340,958–110,341,029, 1 gene: MIR8073.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,239 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:53,970,838–54,671,446, 12 genes, copy number 7 (within-gene range 6–7): ACYP2, RPL21P30, HMGB1P31, AC008280.1, AC008280.2, RNU7-172P, TSPYL6, C2orf73, SPTBN1, SPTBN1-AS1, RPL23AP32, AC092839.1.
- chr2:88,811,186–88,861,563, 1 gene, copy number 10 (within-gene range 6–10): AC244205.1.
- chr2:88,857,161–94,751,293, 122 genes, copy number 10 (broad region; genes not listed).
- chr3:158,962,235–159,897,366, 1 gene, copy number 8 (within-gene range 6–8): IQCJ-SCHIP1.
- chr3:159,282,646–198,222,513, 686 genes, copy number 8–11 (broad region; genes not listed).
- chr5:2,712,591–6,757,044, 53 genes, copy number 7: LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063, AC106799.3, AC106799.2, AC106799.1, AC010634.1, LINC02114, AC026719.1, AC026415.1, AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2, ADAMTS16, AC022424.1, ALG3P1, AC091978.1, MTCO1P30, MTCO2P30, MTCO1P31, ICE1, AC026736.1, AC010266.2, AC010266.1, AC026797.1, HMGB3P3, LINC02145, MED10, AC093307.1, UBE2QL1, AC027334.1, LINC01018, NSUN2, SRD5A1, LINC02102, TENT4A.
- chr5:6,839,460–7,219,291, 1 gene, copy number 7 (within-gene range 6–7): LINC02196.
- chr5:7,047,227–45,228,428, 568 genes, copy number 7–8 (broad region; genes not listed).
- chr6:117,262,243–117,645,087, 12 genes, copy number 8: Z98880.1, VGLL2, ROS1, RN7SKP18, RN7SKP51, AL132671.2, RAP1BP3, AL132671.1, DCBLD1, RNU6-253P, GOPC, NEPNP.
- chr7:56,940,341–65,006,743, 184 genes, copy number 7–8 (broad region; genes not listed).
- chr13:32,586,452–32,788,178, 3 genes, copy number 8 (within-gene range 6–8): PDS5B, RNY1P4, AL138820.1.
- chr17:73,067,870–73,068,288, 1 gene, copy number 7: ATG12P1.
- chr18:2,916,994–3,478,978, 23 genes, copy number 8–15: LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC.
- chr18:3,571,215–3,608,336, 4 genes, copy number 11: RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2.
- chr19:12,938,578–15,419,141, 115 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr20:87,250–20,738,731, 393 genes, copy number 7–10 (broad region; genes not listed).
- chr22:16,671,090–17,132,104, 31 genes, copy number 11: ANKRD62P1, AC005301.1, VWFP1, AC005301.2, LINC01665, XKR3, HSFY1P1, GPM6BP3, AC007064.4, AC007064.3, ZNF402P, AC007064.2, MTND1P17, AC007064.1, AC006548.1, IGKV1OR22-5, IGKV2OR22-4, IGKV2OR22-3, IGKV3OR22-2, IGKV1OR22-1, AC006548.3, GAB4, AC006548.2, VN1R9P, CECR7, AC006946.2, AC006946.3, IL17RA, AC006946.1, TMEM121B, LINC01664.
- chr22:18,077,920–18,131,138, 1 gene, copy number 9 (within-gene range 6–9): PEX26.
- chr22:18,101,612–18,757,906, 28 genes, copy number 9: AC016027.4, ARL2BPP10, TUBA8, AC008079.1, USP18, FAM230D, GGTLC5P, FAM230J, AC011718.1, PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, FAM246B, CA15P2, PPP1R26P2, PPP1R26P4, FAM230E.

Autosomal genes at a single copy (total copy number 1): 206. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
